Somatic mutation profile of tumor specimen TCGA-CN-5367-01A (aliquot TCGA-CN-5367-01A-01D-1434-08) from TCGA case TCGA-CN-5367, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 60.9 years (22,246 days).
Specimen TCGA-CN-5367-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c50fd91-f819-44c6-b9bd-5e335a0f8a2c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-5367-10A (Blood Derived Normal), aliquot TCGA-CN-5367-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e834f71-d600-4bdb-bf0a-37dd0f6a8a65

The open-access MAF lists 101 somatic variants for this specimen: 78 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 20, Splice Site 4, Intron 2, Frame Shift Del 2, Nonsense Mutation 2, 3'UTR 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 9/48 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 17/84 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs193920817, COSV52660939, COSV52789715, COSV53470581; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AC008397.2 | c.1877C>T p.T626M | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1249529810, COSV99441226; called by muse, mutect2
- AGO4 | c.2417A>G p.Y806C | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100942771; called by muse, mutect2
- ATP11A | c.320C>T p.T107M | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371064768; called by muse, mutect2, varscan2
- C14orf39 | c.1349dup p.F451Vfs*4 | Frame Shift Ins (INS) | VAF 62/362 reads (17%) | catalogued as rs776870689; called by mutect2, varscan2
- CD2AP | c.11A>G p.Y4C | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs767423641, COSV63762694; called by muse, mutect2, varscan2
- CLDN15 | c.383-1G>T p.X128_splice | Splice Site (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100385185; called by muse, mutect2, varscan2
- CLMN | c.1622A>T p.K541M | Missense Mutation (SNP) | VAF 13/192 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV100112097; called by muse, mutect2
- CMTR2 | c.208C>G p.L70V | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV100578988; called by muse, mutect2, varscan2
- COL8A2 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100290953; called by muse, mutect2, varscan2
- CUBN | c.4055G>A p.G1352E | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100912080; called by muse, mutect2, varscan2
- DRAXIN | c.137G>A p.G46D | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99610560; called by muse, mutect2, varscan2
- DYNLRB2 | c.107A>G p.N36S | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as rs374532127, COSV58416345; called by muse, mutect2, varscan2
- EFHD2 | c.310T>G p.Y104D | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101044316; called by muse, mutect2
- EPHA5 | c.2921T>A p.L974Q | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99896382; called by muse, mutect2, varscan2
- EPHA7 | c.1345G>T p.V449L | Missense Mutation (SNP) | VAF 11/218 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV100993285, COSV65178093; called by muse, mutect2
- ERCC3 | c.763A>G p.M255V | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs1402080984, COSV99573088; called by muse, mutect2, varscan2
- EXOC4 | c.2317C>T p.R773C | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as rs752361434, COSV99552433; called by muse, mutect2, varscan2
- FIG4 | c.221A>G p.N74S | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100019166; called by muse, mutect2, varscan2
- FLRT3 | c.1679C>T p.S560L | Missense Mutation (SNP) | VAF 61/184 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as rs1395820876, COSV99427382; called by muse, mutect2, varscan2
- GUCY1A2 | c.1322C>G p.S441* | Nonsense Mutation (SNP) | VAF 145/1282 reads (11%) | catalogued as COSV99972906; called by muse, varscan2
- HACD3 | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.37); catalogued as rs768554778, COSV99970918; called by muse, mutect2
- HNRNPK | c.580C>G p.L194V | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.49); catalogued as COSV61088524, COSV61088811; called by muse, mutect2
- HRNR | c.1021G>C p.G341R | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.069); catalogued as rs772853214, COSV100912998; called by muse, mutect2
- HTR3C | c.265C>G p.L89V | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.237); catalogued as COSV100570503; called by muse, mutect2, varscan2
- ITGA10 | c.2006G>A p.R669Q | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.363); catalogued as rs199533163, COSV65195873; called by muse, mutect2, varscan2
- ITGB6 | c.149C>T p.T50I | Missense Mutation (SNP) | VAF 60/206 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV99324166; called by muse, mutect2, varscan2
- KERA | c.832C>A p.P278T | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57131205, COSV99899314; called by muse, mutect2, varscan2
- KRTAP10-6 | c.373T>G p.C125G | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100552013; called by muse, mutect2, varscan2
- LARP1 | c.1675G>T p.E559* (on ENST00000518297 / NM_033551.3; = p.E482* on NM_015315.5 and 6 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 21/82 reads (26%) | catalogued as COSV100303464; called by muse, mutect2, varscan2
- LPAR1 | c.593T>C p.M198T | Missense Mutation (SNP) | VAF 94/168 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100730705; called by muse, mutect2, varscan2
- MGAM | c.179C>G p.P60R | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV101516340; called by muse, mutect2, varscan2
- MUC5B | c.15147C>G p.C5049W | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101500044; called by muse, mutect2, varscan2
- MYOM1 | c.4851C>G p.D1617E | Missense Mutation (SNP) | VAF 502/524 reads (96%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV99865366; called by muse, mutect2, varscan2
- NCKAP5 | c.4964T>C p.L1655P | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as COSV100490131; called by muse, mutect2, varscan2
- NFATC2 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs201848514, COSV65362901; called by muse, mutect2, varscan2
- NOCT | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV99763743; called by muse, mutect2, varscan2
- OGFRL1 | c.1235C>T p.T412I | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs761836813, COSV100965721; called by muse, mutect2, varscan2
- PCDH9 | c.1826T>C p.L609P | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100118575; called by muse, mutect2
- PDE3B | c.1957-1G>C p.X653_splice | Splice Site (SNP) | VAF 35/99 reads (35%) | catalogued as COSV99962026, COSV99962797; called by muse, mutect2, varscan2
- PHKA2 | c.2806+1G>A p.X936_splice | Splice Site (SNP) | VAF 25/85 reads (29%) | catalogued as COSV101176654; called by muse, mutect2, varscan2
- PIK3R5 | c.374A>G p.E125G | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.314); catalogued as COSV52654838; called by muse, mutect2, varscan2
- POLQ | c.6008C>T p.P2003L | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.965); catalogued as rs773624174, COSV51747978; called by muse, mutect2
- PRKDC | c.335C>T p.T112I | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV100031280; called by muse, mutect2
- PTCHD1 | c.786G>T p.Q262H | Missense Mutation (SNP) | VAF 37/219 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.02); catalogued as COSV101037270; called by muse, mutect2, varscan2
- PTPRO | c.1541G>A p.G514D | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as COSV55521397; called by muse, mutect2, varscan2
- PYGB | c.2333A>G p.Y778C | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs199953270, COSV99404874; called by muse, mutect2, varscan2
- REV3L | c.5773C>T p.R1925W | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1447702892, COSV62623387; called by muse, mutect2, varscan2
- SALL3 | c.2708A>G p.Q903R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV101609940; called by muse, mutect2, varscan2
- SCYL1 | c.1526C>T p.P509L | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1162663444, COSV99533780; called by muse, mutect2, varscan2
- SLC16A2 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); catalogued as COSV99330394; called by muse, mutect2
- SLCO5A1 | c.1138A>G p.K380E | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.559); catalogued as COSV99479450; called by muse, mutect2
- SMUG1 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.052); catalogued as COSV54539440; called by muse, mutect2
- SPANXD | c.10C>A p.Q4K | Missense Mutation (SNP) | VAF 42/326 reads (13%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.01); catalogued as COSV100982243; called by muse, mutect2, varscan2
- SPATC1 | c.992C>A p.T331K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.149); catalogued as COSV101084728; called by muse, mutect2, varscan2
- SPIRE1 | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs759567988, COSV100563378; called by muse, mutect2, varscan2
- SPRED3 | c.332C>A p.A111D | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV100612588; called by muse, mutect2, varscan2
- ST6GALNAC2 | c.887A>G p.H296R | Missense Mutation (SNP) | VAF 13/69 reads (19%) | PolyPhen benign (0); catalogued as COSV99833279; called by muse, mutect2, varscan2
- SUCLG2 | c.990C>A p.F330L | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771985145, COSV56214023; called by muse, mutect2, varscan2
- TCIRG1 | c.943C>T p.H315Y | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1337046769, COSV99693119; called by muse, mutect2
- TTC26 | c.351T>C p.A117= | Splice Region (SNP) | VAF 47/173 reads (27%) | catalogued as COSV100570881; called by muse, mutect2, varscan2
- TTN | c.24319C>A p.Q8107K (on ENST00000591111; = p.Q7180K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | PolyPhen benign (0); catalogued as COSV100595526; called by muse, mutect2, varscan2
- VTA1 | c.712A>G p.T238A | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV62660502; called by muse, mutect2, varscan2
- VWF | c.6951C>G p.D2317E | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs755869272, COSV99778075; called by muse, mutect2, varscan2
- WAPL | c.2174A>G p.Y725C | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99556284; called by muse, mutect2, varscan2
- YTHDF1 | c.387C>G p.F129L | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs779558343, COSV100945541, COSV64832738, COSV64833482; called by muse, mutect2, varscan2
- ZMYM2 | c.3262C>G p.L1088V | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as COSV101243537; called by muse, mutect2
- ZNF330 | c.233A>C p.K78T | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99522423; called by muse, mutect2, varscan2
- ZNF462 | c.2342A>G p.Y781C | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.994); catalogued as COSV99470833; called by muse, mutect2
- ZNF471 | c.36C>G p.D12E | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.014); catalogued as COSV100340380; called by muse, mutect2, varscan2
- ZNF654 | c.2206G>C p.D736H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV100525611; called by muse, mutect2, varscan2
- DCN | c.242del p.P81Lfs*6 | Frame Shift Del (DEL) | VAF 10/76 reads (13%) | called by mutect2, pindel, varscan2
- FBXO33 | c.711-13_714del p.X237_splice | Splice Site (DEL) | VAF 32/112 reads (29%) | called by mutect2, pindel
- FPR1 | c.955A>G p.S319G | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.029); called by muse, mutect2
- IGKV3-15 | c.289A>T p.S97C | Missense Mutation (SNP) | VAF 20/231 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2
- ZNF26 | c.967T>A p.F323I | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF513 | c.1131_1133delinsCC p.H378Pfs*2 | Frame Shift Del (DEL) | VAF 32/261 reads (12%) | called by pindel, varscan2*
- CDH11 | c.1128T>C p.D376= | Silent (SNP) | VAF 14/163 reads (9%) | catalogued as COSV99217302; called by muse, mutect2
- CEP55 | c.1293T>C p.A431= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as rs747409579, COSV101016861; called by muse, mutect2, varscan2
- DDB1 | c.369C>A p.I123= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100074333; called by muse, varscan2
- DNAH11 | c.6678T>C p.D2226= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as COSV100177351; called by muse, mutect2, varscan2
- FAM71D | c.615G>A p.V205= | Silent (SNP) | VAF 43/209 reads (21%) | catalogued as COSV100315113; called by muse, mutect2, varscan2
- FHOD1 | c.2664C>T p.A888= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV99263865; called by muse, mutect2, varscan2
- FXYD2 | c.15G>A p.S5= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs746807217, COSV99411335; called by muse, mutect2, varscan2
- H2AC11 | c.154C>T p.L52= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs759054791, COSV100345606, COSV60361617; called by muse, mutect2, varscan2
- H4C11 | c.201C>T p.I67= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs772154105, COSV100747936; called by muse, mutect2, varscan2
- KIZ | c.1230C>A p.A410= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV99851853; called by muse, mutect2, varscan2
- LAP3 | c.321A>G p.G107= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as COSV99884051; called by muse, mutect2
- MACROH2A1 | c.153C>T p.A51= | Silent (SNP) | VAF 26/130 reads (20%) | catalogued as rs1407615203, COSV56893623; called by muse, mutect2, varscan2
- PCLO | c.7704T>G p.S2568= | Silent (SNP) | VAF 54/193 reads (28%) | catalogued as COSV100427670; called by muse, mutect2, varscan2
- PLCB4 | c.1668T>C p.G556= | Silent (SNP) | VAF 49/193 reads (25%) | catalogued as COSV99594490; called by muse, mutect2, varscan2
- RBFOX1 | c.243C>T p.S81= | Silent (SNP) | VAF 33/172 reads (19%) | catalogued as rs1268768787, COSV60951499; called by muse, mutect2, varscan2
- TBC1D14 | c.96C>T p.H32= | Silent (SNP) | VAF 9/128 reads (7%) | catalogued as rs776630489, COSV101298761; called by muse, mutect2
- TF | c.1590A>G p.K530= | Silent (SNP) | VAF 16/110 reads (15%) | catalogued as COSV99395410; called by muse, mutect2, varscan2
- WNK3 | c.993T>C p.V331= | Silent (SNP) | VAF 7/91 reads (8%) | catalogued as COSV100670823; called by muse, mutect2
- ZNF536 | c.3534C>T p.N1178= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as rs775487730, COSV100834707, COSV62836717; called by muse, mutect2, varscan2
- ZSCAN31 | c.975C>T p.C325= | Silent (SNP) | VAF 19/334 reads (6%) | catalogued as COSV100716899; called by muse, mutect2
- EFCAB2 | c.781+3655G>C | Intron (SNP) | VAF 6/66 reads (9%) | catalogued as rs964160103, COSV100833812; called by muse, mutect2
- NFIA | c.*61A>G | 3'UTR (SNP) | VAF 9/92 reads (10%) | catalogued as rs1188590224, COSV100783246; called by muse, mutect2
- RMDN2 | c.452+21558T>C | Intron (SNP) | VAF 11/151 reads (7%) | catalogued as COSV99307322; called by muse, mutect2
